Somatic mutation profile of tumor specimen BLGSP-71-19-00119-09A.1 (aliquot BLGSP-71-19-00119-09A.1-03W-A758-33) from CGCI case BLGSP-71-19-00119, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 12.6 years (4,613 days).
Specimen BLGSP-71-19-00119-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9490f23d-4093-4e56-90d1-eb6c4158dde7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00119-10A (Blood Derived Normal), aliquot BLGSP-71-19-00119-10A-01D-A758-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/909761d1-101d-4ecb-8e99-237843882f5a

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Site 1, Frame Shift Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ID3 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 32/63 reads (51%) | catalogued as COSV65801120; called by muse, varscan2
- MYC | c.445C>G p.L149V (on ENST00000377970; = p.L164V on NM_002467.6) | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV52367523, COSV99420475; called by muse, mutect2, varscan2
- MYC | c.609C>G p.S203R (on ENST00000377970; = p.S218R on NM_002467.6) | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.172); catalogued as COSV104388152; called by muse, mutect2, varscan2
- TFAP4 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52597307; called by muse, mutect2
- ID3 | c.224_240del p.D75Afs*13 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by pindel, varscan2
- MYC | c.685T>C p.S229P (on ENST00000377970; = p.S244P on NM_002467.6) | Missense Mutation (SNP) | VAF 107/358 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TBL1XR1 | c.975T>G p.C325W | Missense Mutation (SNP) | VAF 271/522 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYC | chr8:127735745 C>G | 5'Flank (SNP) | VAF 68/199 reads (34%) | called by muse, mutect2, varscan2
- MYC | c.-45C>G | 5'UTR (SNP) | VAF 86/287 reads (30%) | catalogued as COSV104388204, COSV104388447, COSV104388806; called by muse, varscan2
